Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0HF, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0HF-TTP1-A (Primary Tumor).

[page 1 of 22]
Results History

SURGICAL PATHOLOGY (Order

Result Date - +2

Component Results

Component

Report, pathol

Provider:

Collected:

Case #:

+0

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

BRAIN, OCCIPITAL LOBE MASS. BIOPSY: METASTATIC ADENOCARCINOMA.

Clinical History

Pathology specimens must be accompanied by the traditional PAPER PATHOLOGY REQUISITION.

with brain tumor

Priority:->ROUTINE

Estimated number of specimens: (Label printing use only)->10

Intra-operative Consultation

+0 frozen section diagnosis:

A. Brain tumor, occipital lobe, biopsy: Metastatic adenocarcinoma. (1 chuck/ jel)

Gross Description

Received fresh for frozen section diagnosis labeled with and brain tumor consists of multiple fragments of tan red soft tissue measuring 2 x 1 x 0.5 CM in aggregate.

Representative sections are submitted for frozen section diagnosis.

Frozen section remains are entirely submitted in cassette A1. The remainder of the specimen is formalin fixed and entirely submitted in cassette A2.

+1

Specimen(s) Received

A: BRAIN BIOPSY - brain tumor

Patient Name:

Med. Rec #:

DOB/Age:

Sex: M

Facility:

Location:

Result Date - +1

[page 2 of 22]
Results History

SURGICAL PATHOLOGY (Order # [REDACTED])

Result Date - [REDACTED] +21

Component Results

Component
Report, pathology

Provider: [REDACTED]

Collected: [REDACTED]

+20

Case #: [REDACTED]

Surgical Pathology Report
Addendum Present

FINAL PATHOLOGIC DIAGNOSIS

ESOPHAGUS, BIOPSY:

1. ADENOCARCINOMA, WELL TO MODERATELY DIFFERENTIATED.
2. COLUMNAR GLANDULAR EPITHELIUM WITH INTESTINAL METAPLASIA IN THE FORM OF GOBLET CELLS IDENTIFIED.

** Report Electronically [REDACTED]

Addendum Date Ordered: +625 [REDACTED]

Date Complete: +625 [REDACTED]

Status: Signed Out

By: [REDACTED]

Date Reported: +625 [REDACTED]

This addendum is issued report immunohistochemical evaluation performed by [REDACTED] of the [REDACTED]. Please refer to [REDACTED] report for complete details.

ESOPHAGUS, BIOPSY: - HER2NEU POSITIVE IMMUNOHISTOCHEMISTRY

[REDACTED] Her2neu - positive, 99% tumor cell staining (strong), score (3+)

Clinical History
History of cancer

Gross Description

Received in formalin labeled with [REDACTED] and esophageal biopsies for cancer consists of multiple pink-tan tissue fragments aggregate 0.7 x 0.5 x 0.2 CM; entirely submitted in A1.

+20

Specimen(s) Received

A: ESOPHAGEAL BIOPSY - esophageal bx

Patient Name: [REDACTED]

Med. Rec #: [REDACTED]

DOB/Age: [REDACTED]

Sex: M

Facility: [REDACTED]

Location: [REDACTED]

[page 3 of 22]
[REDACTED]

Results History

[REDACTED]

IMMUNOHISTOCHEMISTRY (Order [REDACTED])

Result Date - [REDACTED] +621

Component Results

Component

Report, pathology

[page 4 of 22]
Component

Provider: [REDACTED]

Collected: [REDACTED]

Case #: [REDACTED]

Immunohistochemistry Report

FINAL PATHOLOGIC DIAGNOSIS

ESOPHAGUS, BIOPSY:

- HER2NEU POSITIVE

IMMUNOHISTOCHEMISTRY ([REDACTED])

Her2neu - positive, 99% tumor cell staining (strong), score (3+)

Studies

[DISCLAIMER: The PATHWAY(tm) HER2 (clone 4B5) test is used to assess HER2 protein overexpression in formalin-fixed, paraffin-embedded tissue. Staining with the PATHWAY(tm) tests is performed in accordance with the Ventana PATHWAY(tm) package insert. Interpretation and scoring of the PATHWAY(tm) tests are performed as follows for gastric carcinoma. A HER2 expression score is assigned (0-3+). Positive cases (HER2 overexpression) are those with a score of 3+. Equivocal cases are those with a score of 2+. Negative cases are those with a score of 1+ or 0. A score of 3+/positive is assigned in surgical samples when moderate to strong complete, basolateral or lateral membrane reactivity is identified in 10% or more of tumor cells, or in biopsy samples with foci of cohesive clusters of five or more tumor cells with strong complete, basolateral or lateral membranous reactivity, irrespective of percentage of tumor cells stained. A score of 2+/equivocal is assigned in surgical samples when weak to moderate complete, basolateral or lateral membrane staining is identified in 10% or more of the tumor cells, and in biopsy samples with clusters of tumor cells with weak to moderate complete, basolateral or lateral membranous reactivity, irrespective of percentage of tumor cells stained. A score of 1+/negative is assigned in surgical samples when faint or barely perceptible staining is identified in 10% or more of the tumor cells, and in biopsy samples with clusters of tumor cells with faint or barely perceptible membranous reactivity irrespective of percentage of tumor cells stained. A score of 0/negative is assigned in surgical samples if no reactivity or faint or barely perceptible membranous reactivity in less than 10% of tumor cells is present, and in biopsy samples if no reactivity is present in any tumor cell.

This assay has not been validated for use on decalcified tissues. Clinicians should interpret the results with caution given the likelihood of false negativity on decalcified specimens. For cases with negative HER2 results by IHC that were decalcified, the specimen will be sent for FISH studies.

Specimens subject to these tests should be fixed in 10% neutral buffered formalin for at least 6 hours, up to a maximum of 72 hours. The volume of formalin should be at least 10 times the volume of the specimen. For cases with negative HER2 results by IHC that were fixed outside these limits, the specimen will be sent for FISH studies.]

Clinical History

FIXATION: Formalin, 6-72 hrs.

For Her2neu study

Specimen(s) Received

[page 5 of 22]
[REDACTED]

Component

A: I-10 CONSULT - HER2NEU Gastric - ESOPHAGEAL BX
1 SL(A1) [REDACTED]

Patient Name: [REDACTED]

Med. Rec #: [REDACTED]

DOB/Age: [REDACTED]

Sex: M

Facility: [REDACTED]

Location: [REDACTED]

[REDACTED]

Result Date - [REDACTED] +618

[page 6 of 22]
Transcription Result

Type	ID	Date	Author
Procedures		+0	

Procedure Orders:

1. CT SOFT TISSUE OF NECK, W CONTRAST [] ordered by at [] +0
2. CT THORAX, W CONTRAST [] ordered by at [] +0
3. CT ABDOMEN AND PELVIS, W CONTRAST [] ordered by at [] +0

Document Text

CT NECK, CHEST, ABDOMEN AND PELVIS

** HISTORY **:

[] gentleman with brain tumor, evaluate for primary source.

Comparison: CT head [] -2

** FINDINGS **:

TECHNIQUE: Gastrointestinal contrast material was administered prior to the study. A preliminary digital scout radiograph was acquired. After the uneventful administration of 100 cc of Omnipaque intravenous contrast, multiple contiguous transaxial images from the base of the skull through the symphysis pubis were obtained along with coronal reconstructions. Images are reviewed in multiple window width and level settings.

CTDI: 14.83, 21.42 mGy

DLP: 2036.99 mGy-cm

Phantom: Body 32

In compliance with [] state regulations, detailed dose information is available and can be accessed by requesting the CT images through the Release of Information (ROI) process. Please contact your local business office or Hospital Information Management office for details.

FINDINGS:

CT NECK

The nasopharynx, oropharynx and hypopharynx are unremarkable. Imaging of the oral cavity is limited by dental artifact.

The parotid and submandibular glands are unremarkable.

No significantly enlarged cervical lymph nodes are identified.

The thyroid, larynx and trachea are normal.

The right parietal-occipital mass is partially visualized with

[page 7 of 22]
adjacent vasogenic edema similar to the previous study.

Again seen is mucosal thickening of the left sphenoid sinus which is partially opacified and mucosal thickening along the lateral wall of the right maxillary sinus.

CT CHEST

Lungs/Pleura: There are mild scattered emphysematous changes throughout the lungs bilaterally. No evidence of consolidation, suspicious masses or pleural effusion. There are mild atelectatic changes in the posterior lung bases bilaterally.

Mediastinum/Hila: No abnormally enlarged lymph nodes are identified. The trachea and bronchi are unremarkable. There is significant wall thickening involving a 5 cm segment of the distal esophagus with an associated hiatal hernia.

Vascular: The heart is normal in size. Coronary arterial stents are seen in the left anterior descending artery.

Chest Wall: Unremarkable.

Musculoskeletal: Mild degenerative changes of the thoracic spine. No obvious aggressive osseous lesions are identified.

CT ABDOMEN/PELVIS

Liver/Gallbladder/Biliary Ducts: There is diffuse fatty infiltration of the liver with areas of sparing. There is a tiny 8mm area of faint hypoattenuation in the medial segment of the left lobe of the liver (axial image #169) which could represent artifact, focal fatty deposition or a discrete liver lesion.

Pancreas: Unremarkable.

Spleen: Unremarkable.

Adrenal Glands: Unremarkable.

Kidneys/Ureters: Symmetric enhancement of the kidneys without evidence of hydronephrosis. There are tiny hypodensities in the kidneys bilaterally which are too small to characterize but statistically are likely to represent cysts.

Stomach/Bowel: Evaluation of the stomach is limited by poor contrast opacification and distention. There is a tiny hiatal hernia with circumferential wall thickening of the distal esophagus. There is apparent wall thickening of the proximal stomach which may be related to underdistention artifact. There is

[page 8 of 22]
no evidence of high-grade small bowel obstruction. There are occasional colonic diverticula without evidence of acute diverticulitis. There is a tiny area of narrowing in the distal sigmoid colon with probably represents spasm. The appendix is normal in caliber.

Vascular: Atherosclerotic changes of abdominal aorta and its branches without evidence of aneurysm.

Lymph Nodes/Retroperitoneum: No abnormally enlarged lymph nodes or bulky lymphadenopathy is identified.

Pelvic Organs: Prostate is not unduly prominent for the patient's age.

Urinary Bladder: Unremarkable.

Free Fluid: No significant free fluid is seen.

Musculoskeletal: Unremarkable for age. No definite aggressive osseous lesions are identified.

Abdominal wall: Tiny umbilical hernia containing fat.

**** IMPRESSION **:**

1. Significant circumferential wall thickening of a 5 cm segment of distal esophagus which is worrisome for neoplastic process. In addition, there is an enlarged gastrohepatic ligament lymph node measuring up to 14 mm along the short axis with low attenuation center. Recommend EGD for further evaluation.

2. Diffuse fatty infiltration of the liver with areas of sparing. There is a faint subcentimeter hypodensity in the medial segment of the left lobe of the liver which is too small to characterize and may represent artifact, focal fatty deposition or a discrete liver lesion.

3. Mild COPD.

See above multiple additional findings.

DD:

+0

DT:

+0

[page 9 of 22]
PACS Images

Show images for PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH

PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH

+394

Results

Status: Final result (Collected: [REDACTED])

Radiology Information

Registration: [REDACTED] +394

Patient Release Status:

This result is not viewable by the patient.

Transcription

Type	ID	Date	Dictating Provider
Procedures	[REDACTED]	[REDACTED]	[REDACTED]
		+395	
PET/CT BASE OF SKULL TO MID THIGH			

**** HISTORY **:**

[REDACTED] male with recurrent esophageal cancer for restaging.

**** FINDINGS **:**

Comparison: [REDACTED] +247

TECHNIQUE: Radiopharmaceutical, 13.6mCi F-18 deoxy glucose.
Fasting blood glucose: 96mg per deciliter.

Approximately 55 minutes following the intravenous administration of the radiopharmaceutical, the patient was placed into the scanner. 7 bed positions with 4 minute emission images were obtained from the base of the skull to mid thighs. Images were reviewed in the sagittal, coronal, and axial planes. Please note that the CT should be considered not fully diagnostic and is used mainly for attenuation and localization purposes.

FINDINGS: A small area of absent tracer activity is again identified within the right parieto-occipital region. No focal abnormal increased radiotracer activity identified along the base of the skull or throughout the neck.

No abnormal tracer deposition identified within either lung. Mediastinal distribution appears physiologic. Calcification of the coronary arteries is again identified and there appears to be one and possibly a second stent within the LAD.

No abnormal radioglucose activity is identified within the liver,

[page 10 of 22]
spleen, pancreas or either adrenal. The expected distribution within the gastrointestinal tract is noted and there is excretion through the genitourinary system. Scattered calcification of the abdominal aorta is identified.

Abnormal radioglucose activity is no longer identified involving the skeletal system with particular attention to the transverse process of the eighth thoracic vertebra.

**** IMPRESSION **:**

+247

1. When compared to prior study of [REDACTED] there appears to have been significant improvement. Abnormal radio tracer activity is no longer identified within the liver, the thoracic vertebra or small posterior mediastinal lymph nodes.
2. Status post right parieto-occipital surgery.
3. Coronary atherosclerosis status post stenting of the LAD.
4. Aortic atherosclerosis.

DD:

DT:

+395

Reason For Exam

Not on file

Imaging

[REDACTED] RESULTS HYPERLINK REPORT: IMAGING DATA (HTML)V2

Order Information

PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH [REDACTED] (Accession [REDACTED]
(Order [REDACTED])

Click on the link for hashtag information

TAGS REPORT

Order Providers

Authorizing Provider

Reviewed in Inbasket

+398

Order Report

Order Details

[page 11 of 22]
PACS Images

Show images for PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH

PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH

Status: Final result (Collected: [REDACTED] +1693

Results

Radiology Information

Registration: [REDACTED] +1693

Patient Release Status:

This result is not viewable by the patient.

Transcription

Type	ID	Date	Dictating Provider
Procedures	[REDACTED]	[REDACTED]	[REDACTED]
PET/CT BASE OF SKULL TO MID THIGH		+1693	

**** HISTORY **:**

[REDACTED] male with esophageal cancer metastatic to brain and liver needs restaging PET.

**** FINDINGS **:**

Comparison: [REDACTED] +506

TECHNIQUE: Radiopharmaceutical, 13.6mCi F-18 deoxy glucose.
Fasting blood glucose: 57mg per deciliter.

Approximately 45 minutes following the intravenous administration of the radiopharmaceutical, the patient was placed into the scanner. 7 bed positions with 4 minute emission images were obtained from the base of the skull to mid thighs. Images were reviewed in the sagittal, coronal, and axial planes. Please note that the CT should be considered not fully diagnostic and is used mainly for attenuation and localization purposes.

FINDINGS: Postsurgical changes are noted along the right occipital lobe without evidence for abnormal radioglucose activity. No abnormal radiotracer activity noted on the base of the skull or throughout the neck.

No abnormal increased radio tracer activity identified within either lung. Mediastinal distribution is physiologic. There is calcification of the coronary arteries and a stent is noted within the left anterior descending coronary artery.

[page 12 of 22]
A 14 mm hypodensity is noted within the posterior right hepatic lobe and there appears to be increased radiotracer activity associated (SUV 4.4). This was not present on the prior study of [REDACTED]. No other abnormal radioglucose activity identified within liver, spleen, pancreas or either adrenal. The expected distribution within the gastrointestinal tract is noted and there is excretion through the genitourinary system. Calcification of the abdominal aorta is noted.

Skeletal distribution of FDG is physiologic.

There are no other significant findings on the CT images other than what corresponds to the above mentioned PET findings or prior CT exams.

**** IMPRESSION **:**

1. New focus of abnormal increased radiotracer activity noted within the posterior right hepatic lobe suspicious for recurrent metastatic disease. No other sites of abnormal uptake identified with particular attention to the brain and the spine.
2. Coronary and aortic atherosclerosis.
3. Status post stenting LAD coronary artery.

DD:

DT:

+1693

Reason For Exam

Not on file

Imaging

RESULTS HYPERLINK REPORT: IMAGING DATA (HTML)V2

Order Information

PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH

Accession
(Order)

Click on the link for hashtag information

TAGS REPORT

Order Providers

Authorizing Provider

Reviewed in Inbasket

[page 13 of 22]
Order Report

Order Details

[page 14 of 22]
PACS Images

Show images for PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH

PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH

Status: Final result (Collected: [REDACTED] +723 [REDACTED])

Results

Radiology Information

Registration: [REDACTED] +723

Patient Release Status:

This result is not viewable by the patient.

Transcription

Type	ID	Date	Dictating Provider
Procedures	[REDACTED]	[REDACTED]	[REDACTED]
		+723	
BASE OF SKULL TO MID-THIGHS FDG PET/CT SCAN			

**** HISTORY **:**

[REDACTED] man with metastatic adenocarcinoma of the gastroesophageal junction diagnosed [REDACTED] +0. He had metastases to the brain and liver. He was treated with chemoradiation, and craniotomy for a right occipital mass. He developed recurrent liver metastases on the last PET/CT from [REDACTED]. His +597 chemotherapy regimen was adjusted and interval PET/CT is requested for response assessment.

Comparison: PET/CT [REDACTED] +597

**** FINDINGS **:****Technique:**

Prior to administration of the radiotracer, the fasting blood glucose level was 58 mg/dl. The patient was positioned on a full ring dedicated PET/CT scanner 53 minutes after intravenous administration of 13.2 mCi of F-18 FDG. A multi-slice spiral CT scan from the base of skull through the mid-thighs was acquired. Emission imaging was then acquired in 3D mode of the same area in 7 bed positions at 4 minutes/bed. Emission images were then corrected for signal attenuation using the CT data before reconstructing in the three orthogonal planes for interpretation together with the CT and CT/PET fused data. Both attenuation corrected and non-attenuation corrected PET data sets were reviewed.

Please note that the CT portion of this study is a relatively low dose multi-slice scan without oral or IV contrast intended only

[page 15 of 22]
for attenuation correction and anatomic correlation of the PET data and is not an independent diagnostic study with respect to the clinical indications.

Findings:

Head and neck:

High normal physiologic FDG uptake in the gray matter limits evaluation for metastatic disease in the brain. However, there is no focus of abnormally increased FDG uptake in the brain to suggest malignancy. Postsurgical changes in the right occipital region from prior craniotomy. The base of the brain is otherwise normal. There is physiologic oropharyngeal uptake. FDG uptake is normal throughout the neck. There are no enlarged lymph nodes in the neck. The thyroid gland is unremarkable.

Chest:

Evaluation of the lung parenchyma is limited by the breathing motion. There is no abnormal FDG uptake in the lungs. There are no pulmonary nodules noted. FDG uptake is normal in the supraclavicular regions and axillae. There are no hypermetabolic or enlarged mediastinal or hilar lymph nodes. There are no pleural or pericardial effusions. There is normal FDG uptake in the heart. The great vessels are normal caliber. There are atherosclerotic calcifications in the aorta. There is a right chest wall port with the tip ending in the distal SVC.

Abdomen and pelvis:

FDG uptake is normal throughout the liver and spleen. The pancreas, gallbladder, and adrenal glands are normal. Physiologic FDG uptake is seen in the bowel. There is physiologic FDG excretion in the kidneys, ureters, and bladder. This high physiologic activity limits evaluation for malignancy of the genitourinary system. There is no adenopathy in the abdomen, pelvis, or inguinal regions. The abdominal aorta is normal caliber. There is no sign of significant free fluid present. There is no free air. The prostate and seminal vesicles are unremarkable. There are punctate, coarse calcifications without abnormal FDG uptake noted in the prostate.

Musculoskeletal:

FDG uptake is normal throughout the skeleton. There are no worrisome lytic or sclerotic lesions.

** IMPRESSION **:

1. There is no metabolically active malignancy. Previously described punctate focus of hypermetabolic activity in the posterior right hepatic lobe is no longer visualized.

[page 16 of 22]
2. Minimal aortic atherosclerotic calcifications.

DD:

DT:

+725

Reason For Exam

Not on file

Imaging

RESULTS HYPERLINK REPORT: IMAGING DATA (HTML)V2

Order Information

PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH (Accession (Order

Click on the link for hashtag information

TAGS REPORT

Order Providers

Authorizing Provider

Reviewed in Inbasket

Order Report

Order Details

[page 17 of 22]
PACS Images

➤ Show images for PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH.

PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH.

Status: Final result (Collected: [REDACTED] +1652

Results

Radiology Information

Registration: [REDACTED] +1652

Patient Release Status:

This result is not viewable by the patient.

Impression

1. There is no sign of metabolically active malignancy.
2. Incidental CT findings including mild aortic atherosclerosis.

Narrative

FDG PET/CT SKULL BASE TO MID THIGH

** HISTORY **:

[REDACTED] man with stage IV gastroesophageal junction adenocarcinoma. Previous PET from [REDACTED] +1533 showed no evidence of disease.

COMPARISON: PET/CT [REDACTED] +1533

** TECHNIQUE **:

BLOOD GLUCOSE: 104 mg/dl

RADIOPHARMACEUTICAL: F-18 FDG (fluorodeoxyglucose) 10.9 mCi IV in the right antecubital vein

FDG UPTAKE TIME: 49 minutes

A low energy, noncontrast CT scan (intended primarily for attenuation correction and anatomic localization; not optimized for visceral and vascular evaluation) was acquired from skull base to mid thighs followed by PET emission scanning of the same anatomic region.

CTDI: 4.21 mGy; DLP: 393.4 mGy-cm

** FINDINGS **:

HEAD/NECK:

LYMPH NODES: No concerning hypermetabolic or enlarged lymph nodes.

BRAIN: No hypermetabolic lesions within limited views of the brain. No significant CT abnormalities.

PARANASAL SINUSES: Clear

OROPHARYNX: No hypermetabolic lesions or abnormal asymmetry.

[page 18 of 22]
THYROID: Normal

CHEST:

LYMPH NODES: No hypermetabolic or enlarged lymph nodes.

LUNGS PARENCHYMA: No hypermetabolic lesions or suspicious CT findings.

LUNGS NODULES/MASSSES: No hypermetabolic nodules or masses.

ESOPHAGUS: No hypermetabolic lesions.

PLEURA/PLEURAL/PERICARDIAL EFFUSIONS: None

VASCULATURE: Mild aortic atherosclerosis. There is an infusion port in the right chest wall with the tip ending in the distal SVC.

ABDOMEN/PELVIS:

LYMPH NODES/MESENTERY: No hypermetabolic lymph nodes. No enlarged nodes by CT criteria.

LIVER: No hypermetabolic lesions.

GALLBLADDER: Normal

STOMACH: No hypermetabolic lesions and limited CT evaluation due to technique.

SPLEEN: No hypermetabolic lesions. Normal in size.

PANCREAS: No hypermetabolic lesions.

ADRENALS: No hypermetabolic lesions.

KIDNEYS/BLADDER: No hypermetabolic lesions outside of physiologic FDG excretion.

BOWEL: No hypermetabolic lesions outside of physiologic bowel uptake.

VASCULATURE: Normal abdominal aortic diameter (<3cm)

PELVIC ORGANS: No hypermetabolic lesions. Pelvic organs are suboptimally evaluated but appear to be grossly normal.

ASCITES/FREE AIR: None

MUSCULOSKELETAL:

BONES: No hypermetabolic lesions. No worrisome lytic, sclerotic or destructive boney lesions.

SOFT TISSUES: Normal.

Report Authenticated by:

Date

Time

+1657

Reason For Exam

Not on file

Imaging

RESULTS HYPERLINK REPORT: IMAGING DATA (HTML)V2

Order Information

PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH.

Click on the link for hashtag information

TAGS REPORT

[page 19 of 22]
Order Providers

Authorizing Provider
[Redacted]

Reviewed in Inbasket

[Redacted]

Order Report

Order Details [Redacted]

[page 20 of 22]
[REDACTED], BL imaging = Day 0

[page 21 of 22]
BL = Day 0. Abnormal distal esophageal thickening, 36 x 37 mm on axial CT. Over 60 mm long on various coronal CT images (arrows)

BL + 4 ½ years = Day 1693
Distal esophagus now appears normal on C-CT (arrow). Normal appearance on 18F FDG PET (fused image - lower center)

[page 22 of 22]
BL = Day 0. Enlarged gastro-hepatic LN , 22 x 12 mm on axial CT. Axial and coronal CT images (arrows)

BL + 4 ½ years = Day 1693
Gastro-hepatic LN now appears normal on C-CT. Normal appearance on 18F FDG PET (fused image - lower center)

Source: NCI Genomic Data Commons file 156914e9-94ef-4b3a-8c71-a6afac883d7b (ER0392 ER-B0HF Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).